Somatic mutation profile of tumor specimen ALCH-B1NQ-TTP1-A (aliquot ALCH-B1NQ-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1NQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 48.0 years (17,539 days).
Specimen ALCH-B1NQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f72b33f9-81ac-4e00-a5f2-4beff4d6c6be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1NQ-NB1-A (Blood Derived Normal), aliquot ALCH-B1NQ-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0db63329-ff42-42bf-954b-aa722892422e

The open-access MAF lists 155 somatic variants for this specimen: 113 protein-altering or splice-affecting, 27 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 27, Nonsense Mutation 6, 3'UTR 5, RNA 4, 5'Flank 3, Intron 2, Translation Start Site 1, Splice Site 1, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP43 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1131692266; ClinVar: pathogenic; called by muse, mutect2
- ATG9A | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.346); catalogued as COSV60133189, COSV60134376; called by muse, mutect2, varscan2
- BNC2 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV66150574; called by muse, mutect2
- BTRC | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV64560360; called by muse, mutect2
- CDC25B | c.689C>T p.S230L (on ENST00000245960 / NM_021873.3; = p.S216L on NM_004358.4) | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs573830932; called by muse, mutect2, varscan2
- CDHR2 | c.1322A>G p.Y441C | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs937127732; called by muse, mutect2
- CNGA3 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 36/664 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs200819699, CM071619, COSV55622355; called by muse, mutect2
- COLEC12 | c.573T>G p.N191K | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV101232142; called by muse, mutect2
- COPS6 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100385224; called by muse, mutect2
- CSPG4 | c.3299G>A p.R1100H | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs146783786; called by muse, mutect2, varscan2
- EZH1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1260794915, COSV52853871; called by muse, mutect2, varscan2
- FBN3 | c.2998G>T p.G1000C | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54455595, COSV99561015; called by muse, mutect2
- HNRNPUL2 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV57133776; called by muse, mutect2, varscan2
- INTS1 | c.3943C>T p.R1315C | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs555209299; called by muse, mutect2, varscan2
- KBTBD11 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104411294; called by muse, mutect2
- LSS | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 49/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150061696; called by muse, mutect2, varscan2
- LYRM9 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1412303833; called by muse, mutect2, varscan2
- NAT8L | c.539C>G p.P180R | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs199612782; called by muse, mutect2, varscan2
- NOXA1 | c.1190dup p.R398Sfs*34 | Frame Shift Ins (INS) | VAF 48/192 reads (25%) | catalogued as rs1367707052; called by mutect2, pindel, varscan2
- OR10J3 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1474450214; called by muse, mutect2, varscan2
- PCDHA8 | c.1215C>A p.Y405* | Nonsense Mutation (SNP) | VAF 76/523 reads (15%) | catalogued as COSV65337560; called by muse, mutect2, varscan2
- PENK | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs367716870; called by muse, mutect2, varscan2
- PHYKPL | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs752620160; called by muse, mutect2, varscan2
- POTEE | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 70/662 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as rs765276298; called by muse, varscan2
- PPFIA3 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs1296984041; called by muse, mutect2, varscan2
- RNF217 | c.1003G>A p.E335K (on ENST00000521654 / NM_001286398.2; = p.E43K on NM_152553.5) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs141934722; called by muse, mutect2
- ROM1 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1412086776; called by muse, mutect2
- SMARCE1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs753397709, COSV99228241; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPEF2 | c.4768A>G p.I1590V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1306913968; called by muse, mutect2, varscan2
- SPINT2 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1386633374, COSV56647908; called by muse, mutect2
- SPTBN4 | c.7142G>A p.R2381Q | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.213); catalogued as rs890625362; called by muse, mutect2
- SSTR5 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs573226759, COSV53511509; called by muse, mutect2, varscan2
- THBS2 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs867528872, COSV64677686, COSV64682722; called by muse, mutect2
- TIMMDC1 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 21/382 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as rs940988515; called by muse, mutect2
- TOGARAM1 | c.2822A>G p.D941G | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs1335936709; called by muse, mutect2
- TP53 | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 154/476 reads (32%) | catalogued as COSV52688866, COSV52766207; called by muse, mutect2, varscan2
- TSHR | c.1663C>T p.L555F | Missense Mutation (SNP) | VAF 49/368 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as rs1315206666; called by muse, mutect2, varscan2
- XCL2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV100892272; called by muse, mutect2
- ZFHX4 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1242458493, COSV51488749; called by muse, mutect2
- ZNF101 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as rs767390576; called by muse, mutect2, varscan2
- ABCA1 | c.65C>G p.T22R | Missense Mutation (SNP) | VAF 20/665 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2
- ABLIM1 | c.341A>C p.Q114P | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- ACKR4 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); called by mutect2, varscan2
- ADAMTSL3 | c.4457G>T p.R1486M | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- APOL5 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.93); called by muse, mutect2
- ARHGAP23 | c.1400G>T p.R467M | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ARHGAP30 | c.2681A>G p.Q894R (on ENST00000368013 / NM_001025598.2; = p.Q683R on NM_181720.3) | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ASXL2 | c.3861G>C p.E1287D | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- B3GLCT | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2
- BACH2 | c.1933G>T p.E645* | Nonsense Mutation (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- CDC23 | c.1446G>C p.E482D | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL18A1 | c.3475A>T p.K1159* (on ENST00000359759 / NM_130444.3; = p.K924* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 43/463 reads (9%) | called by muse, mutect2
- COL5A1 | c.1564C>G p.L522V | Missense Mutation (SNP) | VAF 72/516 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CRABP2 | c.399G>T p.R133S | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYHR1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 26/411 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- DENND11 | c.544C>G p.P182A | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DISP3 | c.1229C>A p.S410* | Nonsense Mutation (SNP) | VAF 28/215 reads (13%) | called by muse, mutect2, varscan2
- EN1 | c.710C>A p.A237E | Missense Mutation (SNP) | VAF 70/445 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EP400 | c.4263G>T p.K1421N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- EPHB6 | c.2830G>A p.V944M | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ESX1 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- FASN | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 139/384 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FEZF2 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, varscan2
- FGL1 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRB3 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 28/519 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HGS | c.1154C>G p.P385R | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HMCN1 | c.13312+1G>C p.X4438_splice | Splice Site (SNP) | VAF 32/297 reads (11%) | called by muse, mutect2
- HOOK3 | c.1662G>C p.K554N | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- IGF2BP1 | c.844C>A p.L282M | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2
- ILRUN | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.033); called by muse, varscan2
- IRX5 | c.494C>G p.A165G | Missense Mutation (SNP) | VAF 76/488 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT5B | c.731G>C p.R244T | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- LAMA2 | c.4352G>A p.C1451Y | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LRRC4 | c.1194C>A p.H398Q | Missense Mutation (SNP) | VAF 21/331 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2
- LYPD3 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MARVELD2 | c.849_851del p.L284del | In Frame Del (DEL) | VAF 44/348 reads (13%) | called by pindel, varscan2
- MAST4 | c.6736G>T p.G2246W (on ENST00000403625 / NM_001164664.2; = p.G2057W on NM_015183.3) | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- MUC12 | c.11172C>G p.S3724R (on ENST00000379442; = p.S3581R on NM_001164462.1) | Missense Mutation (SNP) | VAF 44/1715 reads (3%) | SIFT deleterious (0.01); called by muse, mutect2
- MUC2 | c.2551T>C p.C851R | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NCKAP5L | c.2225G>C p.G742A | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.046); called by muse, mutect2
- NELL1 | c.1607T>C p.V536A | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRBP1 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, varscan2
- NXF3 | c.1449C>G p.S483= | Splice Region (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- OR2T1 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- OR4F6 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAK4 | c.1000A>C p.I334L | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- PCDH9 | c.1790C>G p.T597R | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKAR2B | c.811A>T p.I271F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PRPF19 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRR | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RIPOR2 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.995); called by muse, mutect2
- SELENBP1 | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- SH2D5 | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLIT3 | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTBN2 | c.1144A>G p.K382E | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SSUH2 | c.71G>T p.R24M | Missense Mutation (SNP) | VAF 24/489 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); called by muse, mutect2
- TANGO2 | c.280C>G p.H94D | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- TECTA | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- THAP5 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2
- TIAM1 | c.4219A>C p.S1407R | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2
- TRIM49B | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.421); called by muse, mutect2
- TSPYL5 | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC25 | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- TUBA1C | c.997G>C p.A333P | Missense Mutation (SNP) | VAF 45/413 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TUBB | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- USH1C | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- YWHAZ | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.144); called by muse, varscan2
- ZAR1 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2
- ZBED6CL | c.578G>C p.S193T | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- ZC3HAV1 | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC16 | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF25 | c.422C>G p.S141* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- ZNF605 | c.883A>C p.K295Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.998); called by muse, mutect2
- AGR2 | c.423C>T p.I141= | Silent (SNP) | VAF 13/250 reads (5%) | called by muse, mutect2
- AP4B1 | c.822T>A p.L274= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- ASTN2 | c.1827C>A p.S609= (on ENST00000313400 / NM_001365069.1; = p.S558= on NM_014010.5) | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV100529173; called by muse, mutect2, varscan2
- DEF6 | c.1524C>A p.A508= | Silent (SNP) | VAF 29/759 reads (4%) | called by muse, mutect2
- DSC3 | c.819G>A p.P273= | Silent (SNP) | VAF 58/317 reads (18%) | catalogued as rs374250811; called by muse, mutect2, varscan2
- DUSP22 | c.324C>T p.D108= | Silent (SNP) | VAF 22/551 reads (4%) | catalogued as rs1309090461; called by muse, mutect2
- GAA | c.2727G>C p.V909= | Silent (SNP) | VAF 36/530 reads (7%) | called by muse, mutect2
- GCAT | c.165G>C p.G55= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- GLI2 | c.3396G>A p.V1132= (on ENST00000361492 / NM_001374353.1; = p.V1149= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/642 reads (15%) | called by muse, mutect2, varscan2
- H4C2 | c.162G>A p.E54= | Silent (SNP) | VAF 42/306 reads (14%) | catalogued as rs147907725, COSV99774681; called by muse, mutect2, varscan2
- IFIT5 | c.1206A>G p.E402= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV100877922; called by muse, mutect2, varscan2
- ITGA8 | c.876A>G p.A292= | Silent (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- ITPR3 | c.2862C>T p.S954= | Silent (SNP) | VAF 22/423 reads (5%) | called by muse, mutect2
- KCNH2 | c.3438C>A p.T1146= | Silent (SNP) | VAF 33/252 reads (13%) | called by muse, mutect2, varscan2
- MINDY2 | c.336G>T p.P112= | Silent (SNP) | VAF 19/210 reads (9%) | called by muse, mutect2
- OPLAH | c.501G>T p.V167= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs781869843; called by muse, mutect2
- PSG2 | c.762A>T p.G254= | Silent (SNP) | VAF 42/165 reads (25%) | called by muse, mutect2, varscan2
- RGPD3 | c.5256G>A p.A1752= | Silent (SNP) | VAF 45/320 reads (14%) | catalogued as rs919939501, COSV58737210; called by muse, mutect2, varscan2
- SEL1L2 | c.1203T>A p.A401= | Silent (SNP) | VAF 12/289 reads (4%) | called by muse, mutect2
- SIGLECL1 | c.180C>T p.T60= | Silent (SNP) | VAF 22/303 reads (7%) | called by muse, mutect2
- SOBP | c.1902G>A p.P634= | Silent (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- STRBP | c.954C>A p.A318= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100724223; called by muse, mutect2, varscan2
- TRPM5 | c.1794G>T p.L598= | Silent (SNP) | VAF 82/506 reads (16%) | called by muse, varscan2
- WDR6 | c.966T>C p.I322= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- ZNF775 | c.532C>T p.L178= | Silent (SNP) | VAF 56/391 reads (14%) | called by muse, mutect2, varscan2
- ZNF93 | c.1335C>T p.I445= | Silent (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.1059G>C p.L353= (on ENST00000252463; = p.L408= on NM_032805.3) | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as COSV52969002; called by muse, mutect2, varscan2
- AK2 | c.*3367T>A | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- AP000769.5 | chr11:65498989 T>G | 5'Flank (SNP) | VAF 23/181 reads (13%) | catalogued as rs754397792; called by muse, mutect2, varscan2
- BORCS5 | chr12:12356978 C>T | 5'Flank (SNP) | VAF 11/59 reads (19%) | catalogued as rs757509459; called by muse, mutect2, varscan2
- CHCHD7 | c.153+105G>A | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- DNAJC19 | c.*690A>G | 3'UTR (SNP) | VAF 7/69 reads (10%) | catalogued as rs1370714837, COSV104423365; called by muse, mutect2
- EP400P1 | n.1327A>G | RNA (SNP) | VAF 79/577 reads (14%) | called by muse, mutect2, varscan2
- LINC01973 | n.1419T>A | RNA (SNP) | VAF 22/452 reads (5%) | called by muse, mutect2
- NSG2 | c.*132dup | 3'UTR (INS) | VAF 27/234 reads (12%) | called by mutect2, pindel
- OFCC1 | n.328C>A | RNA (SNP) | VAF 15/273 reads (5%) | called by muse, mutect2
- PUSL1 | c.*36G>T | 3'UTR (SNP) | VAF 21/342 reads (6%) | called by muse, mutect2
- SSPOP | n.4138G>T | RNA (SNP) | VAF 48/475 reads (10%) | called by muse, mutect2, varscan2
- SYBU | c.24+488G>C | Intron (SNP) | VAF 24/367 reads (7%) | catalogued as rs1274542574; called by muse, mutect2
- TMEM220 | c.*8C>T | 3'UTR (SNP) | VAF 8/65 reads (12%) | catalogued as COSV59380309; called by muse, mutect2, varscan2
- TMEM67 | chr8:93819062 A>C | 3'Flank (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
- UCHL5 | chr1:193059640 C>T | 5'Flank (SNP) | VAF 44/596 reads (7%) | catalogued as rs781670691; called by muse, mutect2
